Somatic mutation profile of tumor specimen TCGA-L5-A43M-01A (aliquot TCGA-L5-A43M-01A-11D-A247-09) from TCGA case TCGA-L5-A43M, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: GX; Age at diagnosis: 84.3 years (30,783 days).
Specimen TCGA-L5-A43M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74418a41-65ae-4164-be24-05529ceee2b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A43M-11A (Solid Tissue Normal), aliquot TCGA-L5-A43M-11A-11D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/107bad71-b65a-40a9-a83b-d37dfffaa73e

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 33, Silent 15, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT4 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1049474623; called by muse, mutect2, varscan2
- ARSF | c.1677G>C p.R559S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1312508353; called by muse, mutect2, varscan2
- ASMT | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs373339042, COSV67109849; called by muse, mutect2, varscan2
- CORO7 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs748161669, COSV99227267; called by mutect2, varscan2
- CPB2 | c.442C>G p.H148D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.379); catalogued as COSV51672610; called by muse, mutect2, varscan2
- CRYZL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747446935; called by muse, mutect2, varscan2
- CSPG4 | c.5003G>T p.W1668L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57896492; called by muse, mutect2, varscan2
- ERN2 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99891145; called by muse, mutect2, varscan2
- FMN2 | c.33C>A p.S11R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV60421471; called by muse, mutect2, varscan2
- GGT5 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs762582016, COSV54071734; called by muse, mutect2, varscan2
- HSPA1L | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs529670905; called by muse, mutect2, varscan2
- IGHV1-24 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as rs1555470379; called by muse, mutect2, varscan2
- MDGA1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as rs1449487161, COSV99776398; called by muse, mutect2, varscan2
- OR8D4 | c.512C>A p.S171* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV58431228; called by muse, mutect2, varscan2
- TRPC3 | c.367G>A p.G123S (on ENST00000379645 / NM_001366479.2; = p.G50S on NM_003305.2) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53374492, COSV99313290; called by muse, mutect2, varscan2
- TTC39C | c.1442C>T p.S481L (on ENST00000317571 / NM_001135993.2; = p.S420L on NM_153211.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as rs1478276592; called by muse, mutect2, varscan2
- ZNF157 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV65659856; called by muse, mutect2
- ACLY | c.2895G>T p.K965N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- BRD2 | c.2017dup p.E673Gfs*6 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- CACNA1G | c.5599C>A p.L1867I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CKAP5 | c.4869+1G>T p.X1623_splice | Splice Site (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- COL6A5 | c.6418G>A p.G2140R (on ENST00000312481; = p.G2136R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPS7B | c.322A>T p.M108L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH9 | c.8482G>T p.G2828W | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM124B | c.637G>T p.G213C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRBA1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- NRG3 | c.1839G>T p.M613I (on ENST00000404547 / NM_001370084.1; = p.M589I on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- PCNX4 | c.2176A>T p.T726S (on ENST00000406854 / NM_001330177.2; = p.T492S on NM_022495.5) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PDE11A | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDGFA | c.350T>C p.F117S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM9 | c.1853G>T p.S618I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.618); called by muse, varscan2
- PTPRZ1 | c.3025G>T p.D1009Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RFX7 | c.542C>T p.P181L (on ENST00000559447 / NM_001368074.1; = p.P278L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPGR | c.2557G>A p.E853K (on ENST00000339363 / NM_001367249.1; = p.E648K on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- SOAT1 | c.433T>C p.F145L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SRPK2 | c.606T>G p.D202E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TTN | c.13441C>T p.L4481F (on ENST00000591111; = p.L3554F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF81 | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF15 | c.2097G>A p.P699= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1476037073; called by muse, mutect2, varscan2
- BARHL1 | c.150G>T p.S50= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV55038038; called by muse, mutect2, varscan2
- CAPSL | c.15G>A p.A5= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs370687666; called by muse, mutect2, varscan2
- CDC45 | c.1149G>A p.L383= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV99064205; called by muse, mutect2
- DLL3 | c.708A>G p.E236= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- DNAH10 | c.7344G>T p.L2448= (on ENST00000409039; = p.L2387= on NM_207437.3) | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- DNAH5 | c.9822T>C p.S3274= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV54201229; called by muse, mutect2, varscan2
- LRIT1 | c.1047G>A p.P349= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs560573358, COSV100928063; called by muse, mutect2
- MPI | c.1257C>T p.A419= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- MS4A15 | c.642C>T p.S214= (on ENST00000405633 / NM_001098835.2; = p.S121= on NM_152717.3) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1320126977; called by muse, mutect2, varscan2
- MSH4 | c.723A>G p.Q241= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1396910013; called by muse, mutect2, varscan2
- NELL1 | c.1134C>T p.H378= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs761045422; called by muse, mutect2
- SLC22A2 | c.246C>T p.G82= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs756494902; called by muse, mutect2, varscan2
- TYR | c.246C>T p.S82= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs139926589; called by muse, mutect2, varscan2
- USP51 | c.13C>A p.R5= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
